Somatic mutation profile of tumor specimen TCGA-F7-A623-01A (aliquot TCGA-F7-A623-01A-11D-A28R-08) from TCGA case TCGA-F7-A623, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 70.1 years (25,592 days).
Specimen TCGA-F7-A623-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac88bb65-3fd0-4bf1-859d-6530538f3de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A623-10A (Blood Derived Normal), aliquot TCGA-F7-A623-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67b73338-4a3a-441c-8c48-2f392f06d316

The open-access MAF lists 200 somatic variants for this specimen: 143 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 52, Nonsense Mutation 13, Frame Shift Ins 4, Frame Shift Del 3, Splice Site 3, Splice Region 2, 3'Flank 2, RNA 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4400A>C p.Y1467S | Missense Mutation (SNP) | VAF 49/82 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54328389, COSV99607142, COSV99610059; called by muse, mutect2, varscan2
- UBA5 | c.684G>A p.A228= | Splice Region (SNP) | VAF 14/120 reads (12%) | catalogued as rs1313071575, COSV53906081; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTA1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.993); catalogued as COSV64203706; called by muse, mutect2
- ADAMTS13 | c.4142C>T p.S1381L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99390059; called by mutect2, varscan2
- ADCY2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs1267251314, COSV100601562; called by muse, mutect2, varscan2
- ADCY2 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57874250; called by muse, mutect2, varscan2
- ADCY3 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346616499, COSV99567551; called by muse, mutect2
- ADIPOR1 | c.989T>G p.F330C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV100579364; called by muse, mutect2, varscan2
- AFDN | c.4756G>A p.D1586N | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as rs764193158, COSV100652352; called by muse, mutect2, varscan2
- AMN | c.74T>G p.V25G | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100141405; called by muse, mutect2, varscan2
- ARL5B | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66011063; called by muse, mutect2, varscan2
- ASMT | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs1225747934, COSV101172396; called by muse, mutect2, varscan2
- ATM | c.4516G>A p.V1506M | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as rs760542469, COSV99586954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR1B | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV99215278; called by muse, mutect2, varscan2
- BTBD8 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344094075, COSV61545016; called by muse, mutect2
- CACNA1S | c.2632G>A p.V878M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs202131129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759510146, COSV100754581; called by muse, mutect2, varscan2
- CCDC88B | c.1787C>A p.S596Y | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV100104926, COSV57268705; called by muse, mutect2, varscan2
- CCDC88B | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100104927; called by muse, mutect2, varscan2
- CDC14B | c.495C>T p.F165= | Splice Region (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99685090; called by muse, mutect2, varscan2
- CDH9 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.028); catalogued as COSV99141309, COSV99145337; called by muse, mutect2, varscan2
- CHIA | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV100588540; called by muse, mutect2, varscan2
- COL19A1 | c.1247C>A p.P416H | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as COSV100504951; called by muse, mutect2, varscan2
- COL22A1 | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100275914; called by muse, mutect2
- CSMD3 | c.8515G>T p.V2839F (on ENST00000297405 / NM_001363185.1; = p.V2670F on NM_052900.3) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52100138; called by muse, mutect2, varscan2
- CXXC4 | c.794C>A p.A265E | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101182245; called by muse, mutect2, varscan2
- DBR1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99604359; called by mutect2, varscan2
- DCTN6 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99644832; called by muse, mutect2, varscan2
- DDX18 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99604253; called by muse, mutect2, varscan2
- DHX35 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99326320; called by muse, mutect2, varscan2
- DNAH7 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV100413627; called by muse, mutect2
- DSCAM | c.5814G>T p.K1938N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV101258898; called by muse, mutect2, varscan2
- EPS8L1 | c.1300C>T p.R434C (on ENST00000201647 / NM_133180.3; = p.R307C on NM_017729.3) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV99135580; called by muse, mutect2, varscan2
- EVC2 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100184857; called by muse, mutect2, varscan2
- EYA4 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV100765109; called by muse, mutect2, varscan2
- FARSB | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56050245, COSV99918077; called by muse, mutect2, varscan2
- FAT4 | c.2385G>C p.Q795H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV101271787; called by muse, mutect2, varscan2
- FMN2 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100142237; called by muse, mutect2, varscan2
- FOXK2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV100081741; called by muse, varscan2
- GCA | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV99280392; called by muse, mutect2
- GCLC | c.389T>C p.I130T (on ENST00000643939; = p.I134T on NM_001498.4) | Missense Mutation (SNP) | VAF 44/688 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV99988242; called by muse, mutect2
- GFPT2 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV99517206; called by muse, mutect2
- GRIA2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs1359410555, COSV52395082, COSV99642740; called by muse, mutect2, varscan2
- GRM1 | c.1988T>A p.L663* | Nonsense Mutation (SNP) | VAF 84/355 reads (24%) | catalogued as COSV99263636; called by muse, mutect2, varscan2
- GRM7 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100735417; called by muse, mutect2
- HECTD3 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1294307486, COSV64670261; called by muse, mutect2, varscan2
- HEXD | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV100027539; called by muse, mutect2, varscan2
- HNRNPK | c.847A>G p.M283V | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV100698853; called by muse, mutect2, varscan2
- IPO8 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV99804659; called by muse, mutect2, varscan2
- ITGB1 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 26/163 reads (16%) | catalogued as COSV56479944; called by muse, mutect2, varscan2
- KATNIP | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200936295, COSV99849583; called by muse, mutect2
- KBTBD12 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 11/119 reads (9%) | catalogued as rs529486685, COSV100675335; called by muse, mutect2
- KCNJ14 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV100655709; called by muse, mutect2, varscan2
- KDM6A | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100937864, COSV65045305; called by muse, mutect2, varscan2
- KMT2C | c.14603T>G p.I4868S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100065485; called by muse, mutect2, varscan2
- KRTAP10-5 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100551642; called by muse, mutect2
- KRTAP19-3 | c.115T>A p.C39S | Missense Mutation (SNP) | VAF 139/521 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as COSV100477414; called by muse, mutect2, varscan2
- LEF1 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99489131; called by muse, mutect2, varscan2
- LEXM | c.881A>C p.E294A | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200750891, COSV100827456; called by muse, mutect2
- LILRA5 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56642077, COSV56643278; called by muse, mutect2
- LMTK2 | c.434A>C p.N145T | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV99805862; called by muse, mutect2, varscan2
- LPIN3 | c.1038G>C p.W346C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as COSV100952851, COSV64718256; called by muse, mutect2, varscan2
- LRRC41 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.098); catalogued as rs1427778924, COSV100586041; called by muse, mutect2, varscan2
- MAP3K9 | c.1862A>T p.E621V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.95); catalogued as COSV101173433; called by muse, mutect2, varscan2
- MARCHF11 | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV100197257; called by muse, mutect2
- MARF1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.492); catalogued as rs1212973866, COSV100705574; called by muse, mutect2, varscan2
- MCAT | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as COSV99295565; called by muse, mutect2, varscan2
- MCPH1 | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs770989341, COSV100765181; called by muse, varscan2
- MS4A2 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as COSV99626957; called by muse, mutect2
- MYH11 | c.2015C>T p.T672M | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs749498320, COSV55545607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAT16 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV100296169; called by muse, mutect2, varscan2
- NCAM2 | c.184A>C p.I62L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99520701; called by muse, mutect2, varscan2
- NSD1 | c.4558G>A p.E1520K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1361796691, CM112764, COSV100728342; called by muse, mutect2, varscan2
- OR10X1 | c.727A>T p.R243W | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100936577; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR7E24 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101509630; called by muse, mutect2, varscan2
- PDGFD | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100157578; called by muse, mutect2, varscan2
- PEAK1 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 27/190 reads (14%) | catalogued as COSV56934922; called by muse, mutect2, varscan2
- PHACTR2 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as rs772344848, COSV59856599; called by muse, mutect2
- PPP1R9A | c.146A>C p.E49A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV99194533, COSV99196456; called by muse, mutect2, varscan2
- PRPF3 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100254440; called by muse, mutect2, varscan2
- PTPRZ1 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV101099333; called by muse, mutect2, varscan2
- RAG1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.109); catalogued as rs563167039; called by muse, mutect2
- REG1B | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100521250; called by muse, mutect2, varscan2
- RESF1 | c.4889C>G p.S1630* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100440028; called by muse, mutect2, varscan2
- RGS12 | c.3484C>A p.P1162T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs775199176, COSV100122504; called by muse, mutect2, varscan2
- RIF1 | c.6941+2T>C p.X2314_splice | Splice Site (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99689964; called by muse, mutect2, varscan2
- RP1L1 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101222891, COSV66755956; called by muse, mutect2, varscan2
- SAMHD1 | c.1408A>G p.R470G | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99483759; called by muse, mutect2
- SBF2 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99812872; called by muse, mutect2, varscan2
- SCAMP3 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100226573; called by muse, mutect2, varscan2
- SCN2A | c.2649C>A p.N883K | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99329904; called by muse, mutect2, varscan2
- SETDB1 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776369381, COSV99643573; called by muse, mutect2, varscan2
- SH3PXD2A | c.2105C>A p.S702Y (on ENST00000369774 / NM_001365079.1; = p.S674Y on NM_014631.2) | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100279832, COSV60117055; called by muse, mutect2, varscan2
- SLC25A22 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.591); catalogued as rs1189189617, COSV100204070; called by muse, mutect2
- SLC39A1 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.359); catalogued as rs1331866640, COSV100135302; called by muse, mutect2, varscan2
- SLC4A4 | c.2330C>T p.P777L (on ENST00000264485 / NM_001098484.3; = p.P733L on NM_003759.4) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99138848; called by muse, mutect2
- SLCO4C1 | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs370687578; called by muse, mutect2, varscan2
- SMAD1 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV100129598; called by muse, mutect2
- SNX25 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV99252259; called by muse, mutect2, varscan2
- SPANXN3 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 71/116 reads (61%) | catalogued as COSV100980757; called by muse, mutect2, varscan2
- SPATA16 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100650818; called by muse, mutect2
- SPINDOC | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV53693240, COSV99588414; called by muse, mutect2
- SPINK1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1200211162, COSV99692813; called by muse, mutect2, varscan2
- STAT2 | c.634-2A>G p.X212_splice | Splice Site (SNP) | VAF 12/116 reads (10%) | catalogued as COSV100028548; called by muse, mutect2, varscan2
- STON1 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV100561397; called by muse, mutect2, varscan2
- SYBU | c.1477G>A p.V493M (on ENST00000276646 / NM_001099754.2; = p.V492M on NM_017786.6) | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as COSV99405631; called by muse, mutect2, varscan2
- TEP1 | c.4844C>G p.S1615* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV99401525; called by muse, mutect2, varscan2
- TRPM4 | c.3327C>G p.F1109L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.749); catalogued as COSV99418873; called by muse, mutect2
- TSHZ3 | c.2905T>A p.L969M | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.341); catalogued as COSV99550469; called by muse, mutect2, varscan2
- TTC3 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.019); catalogued as COSV100694939; called by muse, mutect2, varscan2
- TTN | c.66847C>G p.P22283A (on ENST00000591111; = p.P14859A on NM_003319.4) | Missense Mutation (SNP) | VAF 32/262 reads (12%) | PolyPhen probably damaging (0.997); catalogued as COSV100591828; called by muse, mutect2, varscan2
- TTN | c.37769C>A p.P12590H (on ENST00000591111; = p.P5166H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | PolyPhen probably damaging (0.977); catalogued as COSV59996338, COSV60318053; called by muse, mutect2, varscan2
- UBN1 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99277342; called by muse, mutect2, varscan2
- UNKL | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100061174; called by muse, mutect2
- USP17L2 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as COSV100414501; called by muse, varscan2
- UTP25 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV101504717; called by muse, mutect2, varscan2
- VWA3B | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.026); catalogued as COSV101345916; called by muse, mutect2, varscan2
- WDFY3 | c.5987G>C p.R1996T | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV99881712; called by muse, mutect2, varscan2
- WDR13 | c.1046A>T p.H349L | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99489060; called by muse, mutect2, varscan2
- WDR92 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV99718123; called by muse, mutect2
- WIPF2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); catalogued as rs775803870, COSV100063248; called by muse, mutect2, varscan2
- ZBTB1 | c.1850G>C p.R617T | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100703912; called by muse, mutect2, varscan2
- ZC3H6 | c.3002C>T p.S1001L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV100674311; called by muse, mutect2, varscan2
- ZNF292 | c.3176A>G p.N1059S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200889439; called by muse, mutect2, varscan2
- ZNF33B | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100847569; called by muse, mutect2, varscan2
- ZNF521 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201558258, COSV100831345; called by muse, mutect2, varscan2
- ZNF566 | c.1244A>C p.N415T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV101091203; called by muse, mutect2
- ZNF616 | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100348035; called by muse, mutect2, varscan2
- ZNF708 | c.569A>C p.H190P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100803028; called by muse, mutect2, varscan2
- ZNF746 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV100502350; called by muse, mutect2
- ZNF776 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 11/133 reads (8%) | catalogued as COSV100414053, COSV57816432; called by muse, mutect2
- ZNFX1 | c.4732G>C p.E1578Q | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871967, COSV100872051; called by muse, mutect2, varscan2
- APBA2 | c.1251+4_1251+23del p.X417_splice | Splice Site (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel
- EXOC3L1 | c.1505_1522del p.V502_L507del | In Frame Del (DEL) | VAF 33/213 reads (15%) | called by mutect2, pindel*
- GRIFIN | c.304A>C p.K102Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.337); called by muse, mutect2
- ICE1 | c.1230dup p.K411* | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- KIFBP | c.889_893del p.G297Sfs*39 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- LSM14A | c.1089dup p.D364* | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- NT5C3A | c.444dup p.T149Yfs*2 (on ENST00000610140 / NM_001374335.1; = p.T115Yfs*2 on NM_016489.13) | Frame Shift Ins (INS) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- RAB11FIP5 | c.829_836del p.R277Kfs*3 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
- TIE1 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- TP53 | c.266_267dup p.S90Pfs*34 | Frame Shift Ins (INS) | VAF 43/115 reads (37%) | called by mutect2, pindel, varscan2
- AADACL3 | c.682C>T p.L228= | Silent (SNP) | VAF 38/438 reads (9%) | catalogued as COSV100206522; called by muse, mutect2
- CATSPER4 | c.765C>T p.F255= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as COSV100128174; called by muse, mutect2, varscan2
- CCDC136 | c.1263G>A p.R421= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99922019; called by muse, mutect2
- CEP192 | c.3294T>C p.N1098= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100380483; called by muse, mutect2, varscan2
- CLK2 | c.447C>T p.G149= (on ENST00000368361 / NM_001294339.2; = p.G148= on NM_003993.4) | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as rs139020994; called by muse, mutect2, varscan2
- CNTD1 | c.699G>A p.E233= | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as COSV100162031; called by muse, mutect2, varscan2
- COL11A1 | c.246C>A p.L82= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100614776; called by muse, mutect2, varscan2
- COL6A6 | c.375G>T p.G125= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100649715; called by muse, mutect2, varscan2
- CPN1 | c.1296G>A p.R432= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs941110435, COSV100962532; called by muse, mutect2, varscan2
- CYP2E1 | c.1032G>A p.R344= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV99428762; called by muse, mutect2, varscan2
- DCTPP1 | c.105C>A p.R35= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV100073480; called by mutect2, varscan2
- EFHC1 | c.1341C>T p.D447= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as rs749634021, COSV100931859, COSV64136161; called by muse, mutect2, varscan2
- FBXL7 | c.1275G>A p.L425= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100308908; called by muse, mutect2, varscan2
- FLG | c.3666G>A p.K1222= | Silent (SNP) | VAF 229/558 reads (41%) | catalogued as rs768886062, COSV64240708; called by muse, mutect2, varscan2
- G6PC2 | c.624G>A p.L208= | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as rs1418821680, COSV56371631; called by muse, mutect2, varscan2
- GAL3ST4 | c.1335C>T p.P445= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as COSV100385325; called by muse, mutect2, varscan2
- JMY | c.1218G>A p.E406= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs777310925, COSV101267918; called by muse, mutect2, varscan2
- KBTBD3 | c.423C>T p.C141= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV73241229; called by muse, mutect2
- MAGI1 | c.2652C>T p.A884= (on ENST00000402939 / NM_001033057.2; = p.A912= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100439078; called by muse, mutect2, varscan2
- MCM5 | c.1158C>G p.A386= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99331415; called by muse, mutect2, varscan2
- MKRN3 | c.258G>T p.P86= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100090600, COSV58809496; called by muse, mutect2, varscan2
- MYD88 | c.288G>A p.L96= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100085727; called by muse, mutect2, varscan2
- NPC2 | c.318C>T p.T106= | Silent (SNP) | VAF 48/194 reads (25%) | catalogued as COSV99467004; called by muse, mutect2, varscan2
- NSMAF | c.1410A>G p.G470= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV99232257; called by muse, mutect2, varscan2
- PRSS21 | c.621C>G p.L207= | Silent (SNP) | VAF 62/558 reads (11%) | catalogued as COSV99135436; called by muse, mutect2, varscan2
- RBSN | c.72G>A p.Q24= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs574114579, COSV99514951; called by muse, mutect2, varscan2
- RNF121 | c.636C>T p.S212= | Silent (SNP) | VAF 80/167 reads (48%) | catalogued as rs566147682, COSV52619793; called by muse, mutect2, varscan2
- SCN7A | c.1104G>A p.K368= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1444565739, COSV101313060; called by muse, mutect2
- SEPHS2 | c.858G>A p.L286= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV101529299; called by muse, mutect2
- SHISA3 | c.288C>T p.Y96= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as COSV100069759; called by muse, mutect2, varscan2
- SKP2 | c.1110C>T p.I370= | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as rs761744015, COSV57043297; called by muse, mutect2, varscan2
- SLC9A3 | c.1707C>T p.N569= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs772204389, COSV99375606; called by muse, mutect2
- SLCO4A1 | c.1152G>T p.T384= | Silent (SNP) | VAF 51/197 reads (26%) | catalogued as COSV99414413; called by muse, mutect2, varscan2
- SLCO4C1 | c.825C>A p.I275= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV60512361; called by muse, mutect2, varscan2
- SNX29 | c.1488C>T p.D496= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs371383536; called by muse, varscan2
- TDRD1 | c.2409C>T p.I803= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs748563814, COSV99313957; called by muse, mutect2, varscan2
- TMF1 | c.672C>T p.D224= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs199805291, COSV101275391; called by muse, mutect2, varscan2
- TNS4 | c.1776G>A p.V592= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99563513; called by muse, mutect2
- TRRAP | c.5757C>T p.I1919= (on ENST00000359863 / NM_001244580.1; = p.I1901= on NM_003496.3) | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs782296052, COSV100721839; called by muse, mutect2, varscan2
- TTC23L | c.799C>T p.L267= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV101551097; called by muse, mutect2, varscan2
- TTLL2 | c.1548G>C p.T516= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV53444580, COSV99514349; called by muse, mutect2, varscan2
- TUBB8 | c.1044C>T p.N348= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as rs782299458, COSV100225892; called by muse, mutect2
- USH2A | c.126C>T p.N42= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs774473277, COSV56324178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VARS1 | c.3306C>T p.P1102= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs776018811, COSV100791769; called by muse, mutect2
- XIRP2 | c.2040A>G p.E680= (on ENST00000628543; = p.E855= on NM_152381.6) | Silent (SNP) | VAF 56/193 reads (29%) | catalogued as COSV99737663; called by muse, mutect2, varscan2
- ZNF257 | c.1350G>A p.K450= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1330406570, COSV101447996; called by muse, mutect2, varscan2
- ZNF277 | c.75G>T p.G25= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV100702306; called by muse, mutect2
- ZNF341 | c.2355C>A p.P785= (on ENST00000375200 / NM_001282935.1; = p.P778= on NM_032819.4) | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100677626; called by muse, mutect2, varscan2
- ZNF407 | c.2784T>C p.L928= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV99994717; called by muse, mutect2, varscan2
- ZNF574 | c.36T>C p.I12= | Silent (SNP) | VAF 29/275 reads (11%) | catalogued as COSV99725676; called by muse, mutect2, varscan2
- ZNF611 | c.186T>G p.A62= | Silent (SNP) | VAF 27/279 reads (10%) | catalogued as COSV100159953; called by muse, mutect2, varscan2
- ZZEF1 | c.6339C>T p.H2113= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs139607519; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571468 C>G | 3'Flank (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- MIR520D | n.64T>C | RNA (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948725 T>C | 3'Flank (SNP) | VAF 30/126 reads (24%) | catalogued as COSV99987454; called by muse, mutect2, varscan2
- RORA | c.197-25006G>A | Intron (SNP) | VAF 14/119 reads (12%) | catalogued as COSV99832089; called by muse, mutect2, varscan2
- SERPINA13P | n.364C>T | RNA (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
